Somatic mutation profile of tumor specimen ALCH-B2U5-TTP1-A (aliquot ALCH-B2U5-TTP1-A-1-0-D-A77K-36) from ALCHEMIST case ALCH-B2U5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 47.8 years (17,444 days).
Specimen ALCH-B2U5-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2aec9e08-aa5c-40c8-8777-7db606a6799d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2U5-NB1-A (Blood Derived Normal), aliquot ALCH-B2U5-NB1-A-1-0-D-A77K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2acf4d27-7d47-4798-b2a9-4d122f18461e

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Nonsense Mutation 2, Intron 1, Silent 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.158G>A p.W53* | Nonsense Mutation (SNP) | VAF 18/214 reads (8%) | hotspot (GDC flag); catalogued as rs876658483, COSV52774899; ClinVar: pathogenic; called by muse, mutect2
- DNAJB4 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs766243388; called by muse, mutect2
- RDX | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 25/274 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as rs1415646714; called by muse, mutect2
- ABCC9 | c.3245G>A p.R1082K | Missense Mutation (SNP) | VAF 31/379 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGAP19 | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 44/477 reads (9%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.005); called by muse, mutect2
- HSPA12B | c.851C>G p.A284G | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.094); called by muse, mutect2
- LRP12 | c.1268A>T p.N423I | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- LUC7L2 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 11/240 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- RANBP2 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2
- RDX | c.960-2A>G p.X320_splice | Splice Site (SNP) | VAF 31/248 reads (13%) | called by muse, mutect2, varscan2
- RGS7 | c.794G>A p.W265* | Nonsense Mutation (SNP) | VAF 15/265 reads (6%) | called by muse, mutect2
- RTF1 | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 11/271 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HOXA1 | c.792A>T p.A264= | Silent (SNP) | VAF 12/400 reads (3%) | called by muse, mutect2
- KPNB1 | c.*20T>G | 3'UTR (SNP) | VAF 9/201 reads (4%) | called by muse, mutect2
- LYST | c.8358+2803G>A | Intron (SNP) | VAF 33/346 reads (10%) | called by muse, mutect2
